Somatic mutation profile of tumor specimen TCGA-HT-7478-01A (aliquot TCGA-HT-7478-01A-11D-2024-08) from TCGA case TCGA-HT-7478, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 36.2 years (13,216 days).
Specimen TCGA-HT-7478-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f7c4a9c3-36c6-498b-872c-ac47895beab1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7478-10A (Blood Derived Normal), aliquot TCGA-HT-7478-10A-01D-2024-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5f838c13-cbab-45ed-9ce8-f88e88d65a77

The open-access MAF lists 32 somatic variants for this specimen: 27 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 22, Silent 5, Nonsense Mutation 2, Frame Shift Ins 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 30/92 reads (33%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>T p.H1047L | Missense Mutation (SNP) | VAF 12/95 reads (13%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 18/32 reads (56%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATRX | c.6539T>C p.V2180A | Missense Mutation (SNP) | VAF 39/64 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV64873598; called by muse, mutect2, varscan2
- BAZ2B | c.825A>T p.E275D | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs776302170, COSV58597575; called by muse, mutect2, varscan2
- CEP97 | c.352G>C p.E118Q | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV59123459, COSV59128045; called by muse, mutect2, varscan2
- CXCR2 | c.883G>C p.A295P | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59280113; called by muse, mutect2, varscan2
- FSD1 | c.995G>A p.R332H | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs749364630, COSV55695326; called by muse, mutect2, varscan2
- FSHR | c.1653C>A p.H551Q | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.481); catalogued as COSV58620129; called by muse, mutect2, varscan2
- GFAP | c.1271A>G p.N424S | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.003); catalogued as COSV99493589; called by muse, mutect2, varscan2
- GNAO1 | c.1062C>G p.Y354* | Nonsense Mutation (SNP) | VAF 18/70 reads (26%) | catalogued as COSV52612088; called by muse, mutect2, varscan2
- MAU2 | c.1156-1G>A p.X386_splice | Splice Site (SNP) | VAF 37/107 reads (35%) | catalogued as COSV53234311; called by muse, mutect2, varscan2
- MEP1B | c.560A>G p.N187S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52495872, COSV52496386; called by muse, mutect2
- MYO3A | c.63G>C p.W21C | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56323978; called by muse, mutect2, varscan2
- NLRP11 | c.448T>C p.F150L | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.173); catalogued as COSV64086358; called by muse, mutect2, varscan2
- PLA2G4A | c.1873C>G p.P625A | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); catalogued as COSV66552619; called by muse, mutect2, varscan2
- PRDM13 | c.1751G>A p.R584H | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV65029191; called by muse, mutect2
- RAB15 | c.334G>C p.E112Q (on ENST00000533601 / NM_001308154.2; = p.Q155H on NM_198686.3) | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as COSV50824352; called by muse, mutect2
- SETD7 | c.1026dup p.G343Rfs*6 | Frame Shift Ins (INS) | VAF 22/102 reads (22%) | catalogued as rs35259575; called by mutect2, varscan2
- SHFL | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.02); catalogued as rs746145785, COSV53461705, COSV99463454; called by muse, mutect2, varscan2
- SPATA6 | c.1238G>C p.R413T | Missense Mutation (SNP) | VAF 9/200 reads (5%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.946); catalogued as COSV64056698; called by muse, mutect2
- TNFRSF14 | c.470G>T p.S157I | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.447); catalogued as COSV63186160; called by muse, mutect2
- TYR | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs759624945, COSV54469372, COSV54472027; called by muse, mutect2, varscan2
- UGT1A6 | c.625G>C p.V209L | Missense Mutation (SNP) | VAF 64/196 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.232); catalogued as COSV59384825; called by muse, mutect2, varscan2
- UNC13C | c.1702C>T p.Q568* | Nonsense Mutation (SNP) | VAF 12/47 reads (26%) | catalogued as COSV52847178; called by muse, mutect2, varscan2
- ZSCAN5A | c.112G>A p.V38M | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs550648749, COSV54225211; called by muse, mutect2, varscan2
- OR5T3 | c.932del p.K311Rfs*3 | Frame Shift Del (DEL) | VAF 14/74 reads (19%) | called by mutect2, pindel
- MTOR | c.6576G>A p.L2192= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as COSV63869449; called by muse, mutect2, varscan2
- RBFA | c.150G>C p.S50= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as rs1347536822, COSV51533154; called by muse, mutect2, varscan2
- TEAD4 | c.696C>T p.F232= | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as rs1455759065, COSV63280362; called by muse, mutect2
- TRIM35 | c.1254G>A p.S418= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs201064381; called by muse, mutect2
- TUBB4B | c.147G>A p.V49= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV61115941; called by muse, mutect2, varscan2
